Gene-level copy-number profile of tumor specimen TCGA-55-8094-01A from TCGA case TCGA-55-8094, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 51.8 years (18,903 days).
Specimen TCGA-55-8094-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.b8db5862-cc40-4276-90ca-13324afd43c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-8094-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b2ceaf5b-f85e-4a23-9046-c52803af2428

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,805; copy number 2: 24,384; copy number 3: 21,684; copy number 4: 8,427; copy number 5: 2,229; copy number 6: 193; copy number 7: 181; copy number 8: 681; copy number 9: 4; copy number 10: 48; copy number 13: 9; copy number 14: 103; copy number 30: 5; copy number 33: 37; copy number 44: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-8094-01A-11D-2237-01): tumor purity 0.79, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,399 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–164,899,296, 895 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:81,208,193–82,463,675, 12 genes, copy number 5: AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23.
- chr3:161,324,913–170,860,993, 106 genes, copy number 5 (within-gene range 4–13) (broad region; genes not listed).
- chr3:170,691,997–171,054,973, 8 genes, copy number 13 (within-gene range 4–13): AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2.
- chr3:171,106,664–171,106,759, 1 gene, copy number 13: MIR569.
- chr5:58,198–56,606,232, 825 genes, copy number 5–10 (broad region; genes not listed).
- chr8:40,104,169–64,383,787, 360 genes, copy number 5–7 (broad region; genes not listed).
- chr8:67,732,587–81,924,348, 226 genes, copy number 5–44 (broad region; genes not listed).
- chr8:108,871,128–145,066,685, 550 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:30,935,485–31,506,615, 7 genes, copy number 5: FTLP4, HSPA8P17, AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30.
- chr10:38,601,418–38,783,108, 8 genes, copy number 8: ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr12:564,296–911,452, 9 genes, copy number 5: NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1.
- chr12:18,242,961–18,648,416, 1 gene, copy number 14 (within-gene range 4–14): PIK3C2G.
- chr12:18,424,663–26,421,462, 122 genes, copy number 10–14 (broad region; genes not listed).
- chr12:26,335,864–26,373,733, 2 genes, copy number 10: AC055720.2, RNA5SP354.
- chr17:6,628,619–8,630,761, 163 genes, copy number 5 (broad region; genes not listed).
- chr19:22,974,883–24,163,425, 49 genes, copy number 5 (within-gene range 2–5): ZNF728, BNIP3P36, LINC01859, LINC01858, AC074135.2, AC074135.1, ZNF730, BNIP3P37, AC124856.1, SNX6P1, AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr20:58,228,940–60,653,784, 55 genes, copy number 6 (within-gene range 4–6): PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2.

Autosomal genes at a single copy (total copy number 1): 1,372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
